Gene-level copy-number profile of tumor specimen C3N-04092-03 from CPTAC case C3N-04092, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 62.5 years (22,821 days).
Specimen C3N-04092-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ef980a7b-93ce-42cf-8cc0-9eacc865bf96.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-04092-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/9f2bfff5-0d4b-4501-8b6c-b6f88817271b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 9,643; copy number 2: 46,746; copy number 3: 2,369; copy number 4: 22; copy number 17: 8; copy number 21: 31; copy number 22: 16; copy number 24: 4; copy number 89: 1; copy number 92: 1; copy number 97: 5; copy number 100: 2; copy number 102: 1; copy number 112: 2; copy number 114: 1; copy number 117: 4; copy number 129: 3; copy number 142: 1; copy number 150: 1; copy number 199: 1; copy number 218: 2; copy number 231: 6; copy number 240: 10; copy number 246: 2.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:899,462–950,274, 3 genes: LINC01939, AC113607.1, SNTG2-AS1.
- chr2:87,125,198–87,302,251, 5 genes: AC083899.1, MIR4771-1, CENPNP1, LINC01955, DBF4P3.
- chr2:87,379,880–87,380,767, 1 gene: AC068279.1.
- chr2:87,454,781–87,767,359, 6 genes (within-gene range 0–1): CYTOR, AC133644.2, AC133644.1, PAFAH1B1P1, MIR4435-1, RPS14P5.
- chr12:57,723,761–57,742,157, 2 genes (within-gene range 0–17): AGAP2, AGAP2-AS1.
- chr12:59,586,793–59,586,943, 1 gene: RNU4-20P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 102 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:57,253,762–57,431,005, 2 genes, copy number 100 (within-gene range 1–100): R3HDM2, RNU6-879P.
- chr12:57,546,026–57,603,418, 2 genes, copy number 89–102 (within-gene range 1–102): KIF5A, PIP4K2C.
- chr12:57,738,013–58,395,138, 28 genes, copy number 17–150 (within-gene range 0–150): TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1.
- chr12:58,872,149–58,920,504, 1 gene, copy number 92: LRIG3.
- chr12:59,322,765–59,436,874, 3 genes, copy number 129: AC108721.2, AC108721.1, RNU6-279P.
- chr12:59,523,278–59,524,184, 1 gene, copy number 142: LINC02448.
- chr12:60,363,822–60,363,935, 1 gene, copy number 114: AC090022.1.
- chr12:62,466,817–62,600,476, 1 gene, copy number 22 (within-gene range 1–22): MON2.
- chr12:62,545,582–62,622,213, 5 genes, copy number 22: RNU6-399P, LINC01465, AC048341.1, MIRLET7I, AC048341.2.
- chr12:63,142,759–64,162,217, 20 genes, copy number 21 (within-gene range 1–123): AVPR1A, AC135584.1, HNRNPA1P69, AC026116.1, DPY19L2, AC084357.2, AC027667.1, AC084357.3, AC084357.1, RXYLT1, RXYLT1-AS1, PABPC1P4, SRGAP1, RPL36AP41, AC079866.2, AC079866.1, AC020611.1, AC020611.2, AC025576.3, AC025576.2.
- chr12:65,466,820–65,826,997, 6 genes, copy number 24–246 (within-gene range 1–246): AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52.
- chr12:67,443,105–67,590,771, 1 gene, copy number 199 (within-gene range 1–199): LINC02408.
- chr12:68,674,371–68,971,570, 14 genes, copy number 21–231: AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr12:69,326,574–69,584,823, 10 genes, copy number 240: AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2.
- chr12:69,801,669–69,959,097, 2 genes, copy number 218 (within-gene range 1–218): AC025263.2, MYRFL.
- chr12:70,366,290–70,637,440, 5 genes, copy number 97: KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1.

Autosomal genes at a single copy (total copy number 1): 6,792. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
